Gene-level copy-number profile of tumor specimen HTMCP-03-06-02261-01A from CGCI case HTMCP-03-06-02261, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.3 years (18,006 days).
Specimen HTMCP-03-06-02261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c21e664f-abc5-4fd0-9e9a-247ebe868788.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02261-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/03f03b57-116b-47a0-8fdf-d22f1ddd6db5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 1,047; copy number 2: 7,404; copy number 3: 29,162; copy number 4: 10,334; copy number 5: 6,596; copy number 6: 2,544; copy number 7: 772; copy number 8: 199; copy number 9: 44; copy number 10: 52; copy number 11: 50; copy number 13: 18; copy number 14: 22; copy number 18: 18; copy number 20: 21; copy number 23: 1; copy number 26: 32; copy number 29: 29.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,128,103, 17 genes (within-gene range 0–3): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr15:21,927,657–21,946,641, 1 gene: NF1P2.
- chr22:18,178,038–18,653,617, 20 genes: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,258 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:149,569,637–149,587,778, 1 gene, copy number 8 (within-gene range 6–8): MMADHC.
- chr2:203,014,879–203,226,378, 6 genes, copy number 7: NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16.
- chr3:32,236,688–33,441,371, 30 genes, copy number 7–13: AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P.
- chr3:33,727,250–33,869,707, 4 genes, copy number 7: AC112220.1, SDAD1P3, AC112220.2, PDCD6IP.
- chr3:67,360,460–67,654,612, 2 genes, copy number 7: SUCLG2, NDUFB4P1.
- chr7:38,239,580–38,335,514, 15 genes, copy number 11: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:54,752,250–56,323,601, 50 genes, copy number 7–8: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1.
- chr7:65,751,142–67,362,950, 60 genes, copy number 7: CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr7:74,082,933–77,957,503, 114 genes, copy number 7 (broad region; genes not listed).
- chr7:79,654,109–83,362,266, 29 genes, copy number 7: RNA5SP234, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1.
- chr7:104,738,597–104,804,107, 1 gene, copy number 7 (within-gene range 6–7): LHFPL3-AS1.
- chr7:104,894,628–107,564,261, 43 genes, copy number 7 (within-gene range 6–7): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5.
- chr7:107,470,018–107,475,684, 1 gene, copy number 7 (within-gene range 6–7): GPR22.
- chr7:115,647,461–117,230,176, 37 genes, copy number 7 (within-gene range 6–7): AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2.
- chr7:127,346,790–127,431,924, 1 gene, copy number 7 (within-gene range 6–7): ZNF800.
- chr7:127,476,883–131,110,176, 130 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:132,784,870–133,082,090, 1 gene, copy number 7 (within-gene range 6–7): CHCHD3.
- chr7:133,034,607–135,748,813, 42 genes, copy number 7: AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A.
- chr7:142,482,548–142,802,748, 56 genes, copy number 8–11: TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr7:146,116,002–152,855,378, 156 genes, copy number 7 (broad region; genes not listed).
- chr8:39,451,045–43,220,809, 81 genes, copy number 7–10 (broad region; genes not listed).
- chr13:69,700,594–70,108,493, 3 genes, copy number 8 (within-gene range 2–8): KLHL1, RNY3P10, PSMC1P13.
- chr14:21,811,502–22,524,381, 102 genes, copy number 7–26 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 26: TRAC.
- chr17:37,686,431–37,745,105, 1 gene, copy number 7: HNF1B.
- chr17:38,671,703–40,017,813, 73 genes, copy number 14–29 (broad region; genes not listed).
- chr19:14,433,053–16,245,906, 104 genes, copy number 8 (broad region; genes not listed).
- chr19:19,512,418–20,424,969, 60 genes, copy number 7: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2, ZNF682, AC006539.2, AC006539.3, BNIP3P13, ZNF90, AC006539.1, AC011447.5, AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22.
- chr20:32,109,714–33,731,828, 54 genes, copy number 7–9 (within-gene range 5–9): TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1.

Autosomal genes at a single copy (total copy number 1): 280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
